Somatic mutation profile of tumor specimen C3N-02994-01 (aliquot CPT0248000006) from CPTAC case C3N-02994, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G3; Age at diagnosis: 68.7 years (25,102 days).
Specimen C3N-02994-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41304c10-8322-4b5c-841e-ec0f58d5ed36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02994-31 (Blood Derived Normal), aliquot CPT0248020002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ce3e1cc-8997-41d3-8dda-17c46967d72f

The open-access MAF lists 2,056 somatic variants for this specimen: 1,335 protein-altering or splice-affecting, 456 silent, 265 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 976, Silent 456, Frame Shift Del 191, Intron 126, Nonsense Mutation 61, 3'UTR 48, Frame Shift Ins 45, RNA 37, 5'UTR 26, In Frame Del 24, Splice Region 22, 5'Flank 16.

Variants (750 of 2,056; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTB | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 184/437 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as rs104894003, CM061632; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGXT | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); catalogued as rs180177253, CM053748; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AMT | c.59dup p.A21Gfs*7 | Frame Shift Ins (INS) | VAF 72/249 reads (29%) | catalogued as rs386833686; ClinVar: uncertain significance / likely pathogenic; called by mutect2, varscan2
- APC | c.2413C>T p.R805* | Nonsense Mutation (SNP) | VAF 63/211 reads (30%) | catalogued as rs587779783, CM960067, COSV57322578; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.4003C>T p.R1335* | Nonsense Mutation (SNP) | VAF 105/306 reads (34%) | hotspot (GDC flag); catalogued as rs387906846, CM122485, COSV61371872; ClinVar: pathogenic; called by muse, varscan2
- ASPM | c.4732C>T p.R1578* | Nonsense Mutation (SNP) | VAF 127/328 reads (39%) | catalogued as rs753406334, COSV54125634; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.7456C>T p.R2486* | Nonsense Mutation (SNP) | VAF 166/489 reads (34%) | catalogued as rs587779865, CM030195, COSV53747764, COSV53752725; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- COL2A1 | c.2833G>A p.G945S | Missense Mutation (SNP) | VAF 178/532 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs886039542, CM1210170, COSV61533336; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL6A2 | c.2633C>T p.A878V | Missense Mutation (SNP) | VAF 300/534 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774521989, COSV52423839, COSV52424098; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1321C>T p.R441W (on ENST00000281708 / NM_001349798.2; = p.R361W on NM_018315.5) | Missense Mutation (SNP) | VAF 34/116 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55897212, COSV55936558; called by muse, mutect2, varscan2
- GJB2 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 74/181 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs111033190, CM013721, CM023927; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KANSL1 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 44/225 reads (20%) | catalogued as rs149830411; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KCNH2 | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 141/479 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs121912508, CM141792, CM990759, COSV51220645; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, varscan2
- MSH2 | c.2038C>T p.R680* | Nonsense Mutation (SNP) | VAF 415/552 reads (75%) | catalogued as rs63749932, CM970977, COSV51875657; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 43/120 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1057519942, COSV55881590; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- PRRT2 | c.649del p.R217Efs*12 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as rs587778771; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.17_18del p.K6Rfs*4 | Frame Shift Del (DEL) | VAF 151/520 reads (29%) | catalogued as rs121913290; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.968del p.N323Mfs*21 | Frame Shift Del (DEL) | VAF 61/224 reads (27%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- TFAP2B | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 142/436 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1232197674; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 147/429 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TRPM1 | c.1870C>T p.R624C | Missense Mutation (SNP) | VAF 246/698 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387906862, CM101525, COSV56632671; ClinVar: likely pathogenic; called by muse, varscan2
- TTBK1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 107/328 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as rs759748655; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- USP11 | c.1599G>A p.T533= (on ENST00000218348; = p.T490= on NM_001371072.1) | Silent (SNP) | VAF 128/365 reads (35%) | catalogued as rs777516785, COSV54472648, COSV99511021; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.2804G>A p.R935Q | Missense Mutation (SNP) | VAF 79/256 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs766035326, COSV60624046; called by muse, mutect2, varscan2
- ABCA9 | c.2558G>A p.R853H | Missense Mutation (SNP) | VAF 101/318 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.084); catalogued as rs768271528; called by muse, mutect2, varscan2
- ABCB6 | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 92/302 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs374541848, CM146894, COSV54692714; called by muse, mutect2, varscan2
- ABCG4 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs201318219, COSV56646116; called by muse, mutect2, varscan2
- ABHD1 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 74/202 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs368049308; called by muse, varscan2
- ABHD1 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs758121634; called by muse, varscan2
- ABR | c.2526del p.I843Ffs*41 (on ENST00000302538 / NM_021962.5; = p.I806Ffs*41 on NM_001092.5) | Frame Shift Del (DEL) | VAF 61/252 reads (24%) | catalogued as rs750897785; called by mutect2, pindel, varscan2
- ABTB2 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.361); catalogued as rs770620388, COSV54384464; called by muse, mutect2, varscan2
- AC004997.1 | c.1387G>A p.G463S | Missense Mutation (SNP) | VAF 117/387 reads (30%) | SIFT tolerated, low confidence (0.16); catalogued as rs778151331, COSV57575342; called by muse, mutect2, varscan2
- AC011840.1 | n.996G>A | Splice Region (SNP) | VAF 82/265 reads (31%) | catalogued as rs557516586; called by muse, mutect2, varscan2
- AC098582.1 | c.1084_1086del p.H362del | In Frame Del (DEL) | VAF 25/96 reads (26%) | catalogued as rs1477967248; called by pindel, varscan2
- ACACB | c.578G>T p.R193L | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.006); catalogued as COSV58127526; called by muse, mutect2, varscan2
- ACIN1 | c.3806G>A p.R1269Q | Missense Mutation (SNP) | VAF 163/496 reads (33%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.545); catalogued as rs759053676; called by muse, varscan2
- ACO1 | c.2152G>A p.V718I | Missense Mutation (SNP) | VAF 84/237 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as rs542689519; called by muse, mutect2, varscan2
- ACOT7 | c.884G>A p.R295H (on ENST00000377855 / NM_181864.3; = p.R285H on NM_007274.4) | Missense Mutation (SNP) | VAF 105/324 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs1455009318; called by muse, mutect2, varscan2
- ACSM2A | c.323G>A p.R108H (on ENST00000219054; = p.R29H on NM_001308169.2) | Missense Mutation (SNP) | VAF 27/444 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.152); catalogued as rs550591285; called by muse, mutect2
- ACSM2B | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 71/234 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.152); catalogued as rs143779927, COSV61657232; called by muse, mutect2, varscan2
- ADAM19 | c.2567G>A p.R856Q | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as rs556999973; called by muse, mutect2, varscan2
- ADAMTS14 | c.1696C>T p.R566W | Missense Mutation (SNP) | VAF 64/184 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199765284; called by muse, mutect2, varscan2
- ADAMTS6 | c.3181C>T p.R1061W | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58681706; called by muse, varscan2
- ADAMTSL4 | c.2392C>T p.R798W | Missense Mutation (SNP) | VAF 114/310 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs763279620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY4 | c.2951G>A p.R984Q | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780875775; called by muse, mutect2, varscan2
- ADCY9 | c.86G>A p.R29H | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.374); catalogued as COSV99570647; called by muse, mutect2, varscan2
- ADGRA3 | c.2072G>A p.R691H | Missense Mutation (SNP) | VAF 114/388 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201944807; called by muse, mutect2, varscan2
- ADGRB2 | c.2893C>T p.R965C | Missense Mutation (SNP) | VAF 102/280 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57071881; called by muse, mutect2, varscan2
- AFF3 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 51/161 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1326776735, COSV100419954; called by muse, mutect2, varscan2
- AHDC1 | c.2495G>A p.R832H | Missense Mutation (SNP) | VAF 154/429 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs1276300681; called by muse, mutect2, varscan2
- AK9 | c.3407del p.L1136Wfs*35 | Frame Shift Del (DEL) | VAF 39/135 reads (29%) | catalogued as COSV100393511; called by mutect2, pindel, varscan2
- AMDHD2 | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs753112957, COSV53551951; called by muse, mutect2, varscan2
- ANGPTL8 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs774148767; called by muse, mutect2, varscan2
- ANK2 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 168/420 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs772102642, COSV52190603; ClinVar: uncertain significance; called by muse, varscan2
- ANKRD20A4P | c.1376del p.N459Ifs*5 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as rs749182271; called by mutect2, varscan2
- ANKRD30B | c.1447C>T p.R483* | Nonsense Mutation (SNP) | VAF 24/146 reads (16%) | catalogued as rs767362328; called by muse, varscan2
- ANKRD33 | c.224G>A p.R75Q (on ENST00000340970 / NM_001304459.2; = p.R210Q on NM_182608.4) | Missense Mutation (SNP) | VAF 79/243 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.071); catalogued as rs199622035; called by muse, mutect2, varscan2
- ANKS3 | c.1679C>T p.T560M | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs746596153; called by muse, mutect2, varscan2
- ANO3 | c.2395C>T p.R799W | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56779997; called by muse, mutect2, varscan2
- ANO4 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 188/583 reads (32%) | catalogued as rs765845185; called by muse, mutect2, varscan2
- AP002495.1 | c.509G>A p.R170H (on ENST00000528511; = p.R101H on NM_001375848.1) | Missense Mutation (SNP) | VAF 101/303 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1044984255; called by muse, mutect2, varscan2
- AP002748.5 | c.1495C>T p.R499C | Missense Mutation (SNP) | VAF 204/576 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as rs577426256, COSV59146993; called by muse, mutect2, varscan2
- AP3B2 | c.2593C>T p.R865W (on ENST00000261722; = p.R859W on NM_004644.5) | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.99); catalogued as rs201234574, COSV55607570; called by muse, mutect2, varscan2
- AP3D1 | c.2728G>A p.A910T | Missense Mutation (SNP) | VAF 84/213 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750369269; called by muse, mutect2, varscan2
- AP3D1 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 63/244 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777985586; called by muse, mutect2, varscan2
- APBA1 | c.389C>T p.T130M | Missense Mutation (SNP) | VAF 74/219 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.805); catalogued as rs1275599927, COSV99595224; called by muse, mutect2, varscan2
- ARFGEF2 | c.2179C>T p.R727W | Missense Mutation (SNP) | VAF 210/653 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100904393; called by muse, varscan2
- ARFGEF3 | c.4784C>T p.A1595V | Missense Mutation (SNP) | VAF 112/324 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs565406652; called by muse, mutect2, varscan2
- ARG2 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs747904249, COSV104370240; called by muse, mutect2, varscan2
- ARHGAP17 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 75/198 reads (38%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs768561975; called by muse, mutect2, varscan2
- ARHGAP23 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs775996184; called by muse, mutect2, varscan2
- ARHGAP32 | c.3227C>T p.A1076V (on ENST00000310343 / NM_001378025.1; = p.A727V on NM_014715.4) | Missense Mutation (SNP) | VAF 179/502 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.122); catalogued as rs376432253; called by muse, mutect2, varscan2
- ARHGAP9 | c.-20A>G | Splice Region (SNP) | VAF 45/154 reads (29%) | catalogued as rs1350803019; called by muse, mutect2, varscan2
- ARHGEF1 | c.1266C>T p.S422= | Splice Region (SNP) | VAF 73/236 reads (31%) | catalogued as rs782736159; called by muse, mutect2, varscan2
- ARHGEF10 | c.1066G>A p.G356S (on ENST00000398564; = p.G331S on NM_014629.4) | Missense Mutation (SNP) | VAF 222/634 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs767317039; called by mutect2, varscan2
- ARID1B | c.4421C>T p.A1474V | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.06); catalogued as rs370838091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID4B | c.3665C>T p.S1222L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201684035; called by muse, mutect2, varscan2
- ARNTL2 | c.352C>T p.R118W | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs140062821; called by muse, mutect2, varscan2
- ARRB1 | c.167C>T p.T56M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.96); catalogued as rs768631559, COSV63577679; called by muse, mutect2
- ARSD | c.929C>T p.T310M | Missense Mutation (SNP) | VAF 97/313 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.862); catalogued as rs201066862; called by muse, mutect2, varscan2
- ASAP2 | c.2357dup p.L787Afs*16 | Frame Shift Ins (INS) | VAF 36/125 reads (29%) | catalogued as rs773893016; called by mutect2, varscan2
- ASB2 | c.1669C>T p.R557* | Nonsense Mutation (SNP) | VAF 96/280 reads (34%) | catalogued as rs377046730; called by muse, mutect2, varscan2
- ASCL2 | c.461del p.G154Afs*23 | Frame Shift Del (DEL) | VAF 7/63 reads (11%) | catalogued as rs1233059351; called by mutect2, pindel
- ASIC3 | c.535-8C>T | Splice Region (SNP) | VAF 141/423 reads (33%) | catalogued as rs368616729; called by muse, mutect2, varscan2
- ASIC5 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 136/410 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs753653000, COSV72232528; called by muse, mutect2, varscan2
- ATAT1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 95/354 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.272); catalogued as rs772639514; called by muse, mutect2, varscan2
- ATG12 | c.61G>T p.G21* | Nonsense Mutation (SNP) | VAF 76/219 reads (35%) | catalogued as COSV99174635; called by muse, mutect2, varscan2
- ATG2A | c.1925C>T p.T642M | Missense Mutation (SNP) | VAF 135/323 reads (42%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.818); catalogued as rs758825597; called by muse, mutect2, varscan2
- ATP2A2 | c.1943C>T p.T648M | Missense Mutation (SNP) | VAF 237/695 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as rs776014338; called by muse, mutect2, varscan2
- ATP2B4 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 175/465 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs765639720, COSV58182141; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1101del p.T368Lfs*43 | Frame Shift Del (DEL) | VAF 157/592 reads (27%) | catalogued as rs760459265; called by mutect2, pindel, varscan2
- ATP6V1FNB | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs938250276; called by muse, mutect2
- AXL | c.409+1del | Frame Shift Del (DEL) | VAF 10/94 reads (11%) | catalogued as COSV56570524; called by mutect2, pindel, varscan2
- B3GALT4 | c.574C>T p.R192* | Nonsense Mutation (SNP) | VAF 118/301 reads (39%) | catalogued as COSV65852440; called by muse, mutect2, varscan2
- B3GALT6 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55420191; called by muse, mutect2, varscan2
- B3GNT9 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs1024391038, COSV54626847; called by muse, mutect2, varscan2
- BAHCC1 | c.4466G>A p.R1489H | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374320761, COSV100311654; called by muse, mutect2, varscan2
- BAP1 | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 95/256 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1294552464; called by muse, mutect2, varscan2
- BAZ2A | c.2034G>T p.K678N | Missense Mutation (SNP) | VAF 178/515 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV51639642; called by muse, mutect2, varscan2
- BCL7B | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs782452325; called by muse, mutect2, varscan2
- BCORL1 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs1373179389, COSV54398446; called by muse, varscan2
- BDP1 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 63/236 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as rs374639279; called by muse, mutect2, varscan2
- BDP1 | c.938del p.L313* | Frame Shift Del (DEL) | VAF 62/157 reads (39%) | catalogued as rs752427670; called by mutect2, varscan2
- BEND2 | c.734A>G p.N245S | Missense Mutation (SNP) | VAF 58/220 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as rs1410598010; called by muse, mutect2, varscan2
- BIRC6 | c.13304C>T p.T4435I | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs1251124844; called by muse, mutect2, varscan2
- BMP8A | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1302116312, COSV59032846; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 71/242 reads (29%) | catalogued as rs772920507, COSV65808737; called by pindel, varscan2
- BMPR2 | c.1790G>A p.R597Q | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs779639954, COSV65812431; called by muse, varscan2
- BOLL | c.160del p.S54Pfs*6 | Frame Shift Del (DEL) | VAF 33/142 reads (23%) | catalogued as rs1428711101, COSV56578902; called by mutect2, pindel, varscan2
- BPTF | c.5875C>T p.R1959* | Nonsense Mutation (SNP) | VAF 41/184 reads (22%) | catalogued as COSV58845683; called by muse, mutect2, varscan2
- BRWD3 | c.2260G>T p.G754C | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64749691; called by muse, mutect2, varscan2
- BTAF1 | c.4727G>A p.R1576H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1315803278, COSV56430654; called by muse, mutect2, varscan2
- C10orf88 | c.401del p.N134Ifs*2 | Frame Shift Del (DEL) | VAF 58/200 reads (29%) | catalogued as rs751388819; called by mutect2, varscan2
- C11orf54 | c.810del p.F270Lfs*18 (on ENST00000331239; = p.F220Lfs*18 on NM_014039.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 39/63 reads (62%) | catalogued as rs1243082072; called by mutect2, pindel, varscan2
- C12orf56 | c.358_361del p.N120Vfs*37 | Frame Shift Del (DEL) | VAF 60/183 reads (33%) | catalogued as rs754042955; called by pindel, varscan2
- C16orf95 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.133); catalogued as rs567528534, COSV53678109; called by muse, mutect2, varscan2
- C17orf97 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 152/417 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as rs141704289; called by muse, mutect2, varscan2
- C2 | c.980A>G p.N327S | Missense Mutation (SNP) | VAF 189/562 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as rs766665783; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C4orf48 | c.11dup p.P5Afs*? | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | catalogued as rs993464788; called by mutect2, varscan2
- C6orf118 | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.857); catalogued as COSV57816643; called by muse, mutect2, varscan2
- CACNA1A | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.578); catalogued as rs1290079536; called by muse, mutect2, varscan2
- CACNA1E | c.3448G>A p.V1150M | Missense Mutation (SNP) | VAF 85/224 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs546281059; called by muse, mutect2, varscan2
- CACTIN | c.208C>T p.R70* | Nonsense Mutation (SNP) | VAF 41/119 reads (34%) | catalogued as rs1295643587, COSV99698406; called by muse, mutect2, varscan2
- CAD | c.5924G>A p.R1975Q | Missense Mutation (SNP) | VAF 149/388 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769299043, COSV99254372; called by muse, mutect2, varscan2
- CADPS2 | c.3787G>A p.V1263M | Missense Mutation (SNP) | VAF 50/111 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV57386610; called by muse, mutect2, varscan2
- CALD1 | c.1535G>A p.R512H (on ENST00000361675 / NM_033138.4; = p.R257H on NM_004342.7) | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV62654464; called by muse, mutect2, varscan2
- CAMK2A | c.1369C>T p.R457C (on ENST00000348628 / NM_171825.2; = p.R468C on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 210/541 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs754732557; called by muse, mutect2, varscan2
- CAND1 | c.95C>T p.T32M | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs759442057; called by muse, mutect2, varscan2
- CARD11 | c.2924G>A p.R975Q | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764229454; called by muse, mutect2, varscan2
- CARMIL2 | c.2174C>A p.P725H | Missense Mutation (SNP) | VAF 120/249 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV58029917; called by muse, mutect2, varscan2
- CARNS1 | c.671C>A p.P224H | Missense Mutation (SNP) | VAF 90/242 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs1272256023; called by muse, mutect2, varscan2
- CASP7 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 149/495 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764815610, COSV61880865; called by muse, mutect2, varscan2
- CAV3 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 100/304 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.061); catalogued as rs921802744, COSV100373086; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBFA2T3 | c.599G>A p.R200H | Missense Mutation (SNP) | VAF 85/286 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as rs758562596, COSV51927785; called by muse, mutect2, varscan2
- CCDC102A | c.1457G>A p.R486Q | Missense Mutation (SNP) | VAF 116/364 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs755446173; called by muse, mutect2, varscan2
- CCDC116 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs781434365, COSV53037078; called by muse, mutect2, varscan2
- CCDC130 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 73/217 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1222629626; called by muse, mutect2, varscan2
- CCDC14 | c.2644C>T p.R882C (on ENST00000488653; = p.R834C on NM_022757.5) | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs777030806, COSV59944850; called by muse, mutect2, varscan2
- CCDC168 | c.7808A>G p.D2603G | Missense Mutation (SNP) | VAF 66/186 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751726221; called by muse, varscan2
- CCDC171 | c.1454C>T p.T485M | Missense Mutation (SNP) | VAF 61/176 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.51); catalogued as rs542083759, COSV52635355; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 46/158 reads (29%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC34 | c.962G>T p.W321L | Missense Mutation (SNP) | VAF 57/227 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60821027; called by muse, mutect2, varscan2
- CCDC71 | c.1300C>T p.R434W | Missense Mutation (SNP) | VAF 22/373 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1006250262; called by muse, mutect2
- CCDC88B | c.3176C>T p.A1059V | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs777401623, COSV57265137; called by muse, mutect2, varscan2
- CCDC88B | c.3823C>T p.R1275W | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs148105094; called by muse, mutect2, varscan2
- CCDC88C | c.2704G>A p.V902M | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs755522236; called by muse, mutect2, varscan2
- CCDC9 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 72/203 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs376833190; called by muse, mutect2, varscan2
- CCDC9 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 97/283 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770418476; called by muse, mutect2, varscan2
- CCKBR | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 91/308 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs749320440, COSV58100360; called by muse, mutect2, varscan2
- CCNA1 | c.1101C>T p.Y367= | Splice Region (SNP) | VAF 22/64 reads (34%) | catalogued as rs1015130861; called by mutect2, varscan2
- CCNF | c.1796C>T p.T599M | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as rs1177557365; called by muse, mutect2, varscan2
- CCNO | c.935C>T p.A312V | Missense Mutation (SNP) | VAF 219/652 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1345027151, COSV99248220; called by muse, mutect2, varscan2
- CCT7 | c.1615C>T p.R539C | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.973); catalogued as rs547857492; called by muse, mutect2, varscan2
- CD1C | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 74/236 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777045453, COSV63806397; called by muse, mutect2, varscan2
- CD27 | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 105/280 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs772449872, COSV56951357; called by muse, mutect2, varscan2
- CDC42BPA | c.4876C>T p.R1626C (on ENST00000334218 / NM_001366019.2; = p.R1613C on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 128/436 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs756238413, COSV62012840; called by muse, mutect2, varscan2
- CDH2 | c.2678G>A p.R893Q | Missense Mutation (SNP) | VAF 172/461 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs201294768, COSV52284491; called by muse, mutect2, varscan2
- CDHR2 | c.3652C>T p.R1218* | Nonsense Mutation (SNP) | VAF 102/280 reads (36%) | catalogued as rs760896613; called by muse, mutect2, varscan2
- CDK3 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 91/255 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs762715989, COSV101159374; called by muse, mutect2, varscan2
- CDKL4 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 103/356 reads (29%) | catalogued as rs771548328, COSV101115322, COSV66509906; called by muse, mutect2, varscan2
- CEP95 | c.1568G>A p.R523H | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs782568738, COSV73609620; called by muse, mutect2, varscan2
- CFAP46 | c.3100G>A p.A1034T | Missense Mutation (SNP) | VAF 87/273 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as rs777460078; called by muse, mutect2
- CFAP47 | c.9107C>T p.T3036M | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.073); catalogued as rs143613641, COSV101074069; called by muse, mutect2, varscan2
- CFAP54 | c.4253del p.K1418Rfs*4 | Frame Shift Del (DEL) | VAF 20/55 reads (36%) | catalogued as rs1274191949; called by mutect2, varscan2
- CHADL | c.884dup p.L296Afs*199 | Frame Shift Ins (INS) | VAF 48/157 reads (31%) | catalogued as rs1446920828; called by mutect2, pindel, varscan2
- CHAF1A | c.1568C>T p.T523M | Missense Mutation (SNP) | VAF 26/434 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750776567; called by muse, mutect2
- CHD5 | c.3332C>T p.T1111M | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52413013; called by muse, mutect2, varscan2
- CHI3L2 | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs1272447761; called by muse, mutect2, varscan2
- CHRNA4 | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 110/303 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.071); catalogued as rs746557446; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHST2 | c.1159G>A p.A387T | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); catalogued as COSV100536038; called by muse, mutect2, varscan2
- CHST6 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 275/814 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as rs765859166, COSV60001885; called by muse, mutect2, varscan2
- CIITA | c.1962del p.A656Pfs*30 | Frame Shift Del (DEL) | VAF 95/329 reads (29%) | catalogued as COSV60863473; called by mutect2, pindel, varscan2
- CLCN6 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 143/353 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as rs538878178, COSV100411549; called by muse, mutect2, varscan2
- CLUH | c.1189G>A p.A397T (on ENST00000435359; = p.A435T on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs748785564, COSV101425669; called by muse, mutect2, varscan2
- CNBD2 | c.109C>T p.R37C | Missense Mutation (SNP) | VAF 66/240 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs539557197, COSV62588051; called by muse, mutect2, varscan2
- CNGA4 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 108/349 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.174); catalogued as rs1410764626, COSV66007293; called by muse, mutect2, varscan2
- CNNM4 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 91/275 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV65661880; called by muse, mutect2, varscan2
- CNTN2 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 126/305 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.088); catalogued as rs373583840; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CNTN4 | c.979G>A p.V327M | Missense Mutation (SNP) | VAF 80/227 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as rs562479085, COSV61875419, COSV61877230; called by muse, mutect2, varscan2
- COL16A1 | c.3320G>A p.R1107H | Missense Mutation (SNP) | VAF 111/316 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs34013895; called by muse, mutect2, varscan2
- COL5A3 | c.1793C>T p.P598L | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.894); catalogued as rs147814824; called by muse, mutect2, varscan2
- COL6A3 | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 134/327 reads (41%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as rs762162177; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPEB1 | c.685C>T p.R229C (on ENST00000617958; = p.R169C on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs762664847, COSV55618480; called by muse, mutect2, varscan2
- CPT1B | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 72/209 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as rs776509386; called by muse, mutect2, varscan2
- CRB2 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as rs771641406; called by muse, varscan2
- CROCC2 | c.3121G>A p.V1041M | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.042); catalogued as rs749862655; called by muse, mutect2, varscan2
- CROCC2 | c.3436del p.D1146Tfs*13 | Frame Shift Del (DEL) | VAF 99/326 reads (30%) | catalogued as rs1255916134; called by mutect2, varscan2
- CRYBG2 | c.3767G>A p.R1256Q | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.315); catalogued as rs867674704, COSV57486670; called by muse, varscan2
- CSMD2 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 61/223 reads (27%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV53922566; called by muse, mutect2, varscan2
- CSMD2 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 109/280 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs771665223, COSV99594667; called by muse, mutect2, varscan2
- CSNK1E | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 142/441 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.034); catalogued as rs1230602951, COSV104417268; called by muse, mutect2, varscan2
- CSTF2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1366719927; called by muse, mutect2, varscan2
- CTDP1 | c.440C>T p.T147M | Missense Mutation (SNP) | VAF 254/651 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143464787; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CUX1 | c.4258G>A p.A1420T | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.34); PolyPhen benign (0.028); catalogued as rs1420389396; called by muse, mutect2, varscan2
- CUX2 | c.1721G>A p.R574Q | Missense Mutation (SNP) | VAF 114/354 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1268769789, COSV99919319; called by muse, mutect2, varscan2
- DAB2IP | c.3266G>A p.R1089Q (on ENST00000408936; = p.R1061Q on NM_032552.3) | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs1343675566, COSV52267754; called by muse, mutect2, varscan2
- DACT1 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 135/414 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs200570611, CM161816; called by muse, mutect2, varscan2
- DACT3 | c.1130G>A p.R377H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.745); catalogued as rs1191821869; called by muse, mutect2, varscan2
- DAGLA | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as rs1257229518, COSV57200291; called by muse, mutect2
- DAGLB | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 129/335 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs758965312; called by muse, mutect2, varscan2
- DAPK3 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as rs756550520, COSV56662684; called by muse, mutect2, varscan2
- DCAF1 | c.2749G>A p.A917T | Missense Mutation (SNP) | VAF 176/510 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs782779656; called by muse, varscan2
- DCAF12 | c.766C>T p.R256W | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1389127939, COSV100778368; called by muse, mutect2
- DCHS1 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 73/201 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370993279; called by muse, mutect2, varscan2
- DDI1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 87/231 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs753855229; called by muse, mutect2, varscan2
- DDR1 | c.2468C>T p.A823V (on ENST00000324771; = p.A786V on NM_001954.4) | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs368093405; called by muse, mutect2, varscan2
- DDR2 | c.1831C>T p.R611* | Nonsense Mutation (SNP) | VAF 22/636 reads (3%) | catalogued as rs928746429, COSV63373001; ClinVar: uncertain significance; called by muse, mutect2
- DDR2 | c.2125C>T p.R709* | Nonsense Mutation (SNP) | VAF 155/414 reads (37%) | catalogued as rs1056323839, COSV63370359; called by muse, mutect2, varscan2
- DDX39B | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); catalogued as rs267600954, COSV100795270; called by muse, mutect2, varscan2
- DDX3X | c.1675_1677del p.L559del (on ENST00000399959; = p.L560del on NM_001356.5) | In Frame Del (DEL) | VAF 41/145 reads (28%) | catalogued as rs1555954380; called by pindel, varscan2
- DEFB129 | c.333del p.F111Lfs*15 | Frame Shift Del (DEL) | VAF 138/496 reads (28%) | catalogued as rs765896284; called by mutect2, pindel, varscan2
- DHX35 | c.2066C>T p.T689M | Missense Mutation (SNP) | VAF 89/238 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as rs778423906, COSV52670403; called by muse, mutect2, varscan2
- DIAPH2 | c.1006C>A p.L336I | Missense Mutation (SNP) | VAF 51/226 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV61294695; called by muse, mutect2, varscan2
- DIRAS1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 93/258 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs775310063, COSV60216413; called by muse, mutect2, varscan2
- DLG4 | c.1951C>T p.R651C (on ENST00000399506 / NM_001321075.3; = p.R694C on NM_001365.4) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs1290892445, COSV57240752; called by muse, mutect2
- DLGAP1 | c.1756C>T p.L586F | Missense Mutation (SNP) | VAF 149/442 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV100229409; called by muse, mutect2, varscan2
- DNAH1 | c.7076G>A p.R2359H | Missense Mutation (SNP) | VAF 130/426 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs748543554, COSV70233697; called by muse, mutect2, varscan2
- DNAH14 | c.3419C>T p.T1140M (on ENST00000445597; = p.T1524M on NM_001367479.1) | Missense Mutation (SNP) | VAF 126/365 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201873499; called by muse, mutect2, varscan2
- DNAH3 | c.8578C>T p.R2860W | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs544228596, COSV99769821; called by muse, mutect2, varscan2
- DNAH9 | c.3790G>A p.E1264K | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as rs756428546, COSV52335454; called by muse, mutect2, varscan2
- DNAJC16 | c.680_682del p.S227del | In Frame Del (DEL) | VAF 54/230 reads (23%) | catalogued as rs766218747; called by mutect2, pindel, varscan2
- DNAJC2 | c.1173-7del | Splice Region (DEL) | VAF 78/204 reads (38%) | catalogued as rs538091160; called by mutect2, varscan2
- DNAJC21 | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 103/314 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1340350407, COSV100331646; called by muse, mutect2, varscan2
- DNER | c.1823C>T p.P608L | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs368405241, COSV59171289; called by muse, mutect2, varscan2
- DNHD1 | c.7681C>T p.R2561* | Nonsense Mutation (SNP) | VAF 123/407 reads (30%) | catalogued as rs779590433; called by muse, mutect2, varscan2
- DNMBP | c.4714C>T p.R1572C | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as rs752233660, COSV100143951, COSV60628347; called by muse, mutect2
- DNMT1 | c.4271G>A p.R1424H | Missense Mutation (SNP) | VAF 74/214 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1183358759; called by muse, mutect2, varscan2
- DOCK10 | c.5981C>T p.A1994V | Missense Mutation (SNP) | VAF 116/299 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.184); catalogued as rs544760670; called by muse, mutect2, varscan2
- DOCK3 | c.5499del p.G1834Vfs*63 | Frame Shift Del (DEL) | VAF 74/233 reads (32%) | catalogued as rs34788750; called by mutect2, pindel, varscan2
- DOCK8 | c.5710C>T p.R1904W | Missense Mutation (SNP) | VAF 107/309 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772585700, COSV66623055; called by muse, mutect2, varscan2
- DOK1 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51211765; called by muse, mutect2, varscan2
- DOP1B | c.5938G>A p.A1980T | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs370211956; called by muse, mutect2, varscan2
- DOT1L | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 92/250 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745691240; called by muse, mutect2, varscan2
- DPP7 | c.67+1del p.X23_splice | Splice Site (DEL) | VAF 17/56 reads (30%) | catalogued as rs1564326751; called by mutect2, pindel, varscan2
- DUS3L | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 112/304 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.587); catalogued as rs765884809; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1060del p.W354Gfs*2 | Frame Shift Del (DEL) | VAF 41/126 reads (33%) | catalogued as rs746928635; called by mutect2, pindel
- DVL2 | c.1849G>A p.G617S | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.087); catalogued as rs759698030, COSV50035136; called by muse, mutect2, varscan2
- DYNC2H1 | c.6809G>A p.R2270Q | Missense Mutation (SNP) | VAF 110/339 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); catalogued as rs1232553987, COSV62094656; called by muse, mutect2, varscan2
- DYNLRB1 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.668); catalogued as rs1223348566, COSV55964731; called by muse, mutect2, varscan2
- DYSF | c.1768C>T p.R590C | Missense Mutation (SNP) | VAF 152/467 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs745472489, COSV50560985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EDIL3 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as rs370618954; called by muse, mutect2, varscan2
- EFCAB13 | c.190dup p.I64Nfs*3 | Frame Shift Ins (INS) | VAF 15/51 reads (29%) | catalogued as rs995188950; called by mutect2, varscan2
- EFCAB14 | c.1237_1238del p.Q413Vfs*7 | Frame Shift Del (DEL) | VAF 64/257 reads (25%) | catalogued as rs773560951; called by pindel, varscan2
- EFHC1 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 86/273 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100931834; called by muse, mutect2, varscan2
- EFTUD2 | c.493-4del | Splice Region (DEL) | VAF 54/206 reads (26%) | catalogued as rs779361868; called by mutect2, varscan2
- EHD2 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as rs1366247820, COSV54411595; called by muse, mutect2, varscan2
- EIF4B | c.988dup p.Q330Pfs*14 | Frame Shift Ins (INS) | VAF 20/48 reads (42%) | catalogued as rs747252313; called by mutect2, varscan2
- EIF4G1 | c.1305del p.T436Pfs*86 (on ENST00000346169 / NM_198241.3; = p.T240Pfs*86 on NM_004953.5) | Frame Shift Del (DEL) | VAF 60/204 reads (29%) | catalogued as COSV104407217; called by mutect2, pindel, varscan2
- ELFN2 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 103/296 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs767275235, COSV68745454; called by muse, mutect2, varscan2
- ELK1 | c.1049C>T p.P350L | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs772662025; called by muse, mutect2, varscan2
- ENG | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 90/310 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770898485, CM052868; called by muse, mutect2, varscan2
- ENPEP | c.2075G>A p.W692* | Nonsense Mutation (SNP) | VAF 32/149 reads (21%) | catalogued as rs1295292195, COSV54451585, COSV54453023; called by muse, mutect2, varscan2
- EP400 | c.4046C>T p.A1349V | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.127); catalogued as rs541165241, COSV100201417; called by muse, mutect2, varscan2
- EPB41L2 | c.1636C>T p.R546W | Missense Mutation (SNP) | VAF 64/194 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149647551; called by muse, varscan2
- EPHA6 | c.2499del p.R834Gfs*8 (on ENST00000389672 / NM_001080448.3; = p.R226Gfs*8 on NM_173655.4) | Frame Shift Del (DEL) | VAF 32/95 reads (34%) | catalogued as rs765418329; called by mutect2, pindel, varscan2
- EPS8 | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs200527909; called by muse, mutect2, varscan2
- ERAS | c.523del p.A175Pfs*67 | Frame Shift Del (DEL) | VAF 53/184 reads (29%) | catalogued as rs782765893; called by mutect2, pindel, varscan2
- ERBB2 | c.2896C>T p.R966W | Missense Mutation (SNP) | VAF 150/440 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753151506; called by muse, mutect2, varscan2
- ERC2 | c.1492C>T p.R498* | Nonsense Mutation (SNP) | VAF 51/136 reads (38%) | catalogued as rs1440705306, COSV55612369; called by muse, mutect2, varscan2
- ERF | c.896del p.G299Efs*12 | Frame Shift Del (DEL) | VAF 114/463 reads (25%) | catalogued as rs780487406; called by mutect2, pindel, varscan2
- ERICH6B | c.950del p.K317Rfs*18 | Frame Shift Del (DEL) | VAF 39/166 reads (23%) | catalogued as rs754232917, COSV100074795; called by mutect2, pindel, varscan2
- ERN1 | c.319T>C p.S107P | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV70500582; called by muse, varscan2
- ERVV-2 | c.878C>T p.T293M | Missense Mutation (SNP) | VAF 105/218 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.253); catalogued as rs556976940; called by muse, mutect2, varscan2
- ESF1 | c.1518G>A p.T506= | Splice Region (SNP) | VAF 61/229 reads (27%) | catalogued as rs373675586; called by muse, mutect2, varscan2
- FAM114A2 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.492); catalogued as rs775272637, COSV61076820; called by muse, mutect2, varscan2
- FAM117B | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 79/200 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.236); catalogued as rs751809497; called by muse, mutect2, varscan2
- FAM120A | c.1283C>T p.T428M | Missense Mutation (SNP) | VAF 186/568 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs145417293; called by muse, mutect2, varscan2
- FAM151A | c.1289G>A p.R430H | Missense Mutation (SNP) | VAF 167/500 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs549597401; called by muse, mutect2, varscan2
- FAM181B | c.1021dup p.R341Pfs*96 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | catalogued as rs770611228; called by mutect2, pindel, varscan2
- FAM193A | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 84/257 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.325); catalogued as rs970104123, COSV61195975; called by muse, mutect2, varscan2
- FAM222B | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.992); catalogued as rs771651778, COSV57928144; called by muse, mutect2, varscan2
- FAM222B | c.1232C>T p.P411L | Missense Mutation (SNP) | VAF 48/145 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.74); catalogued as rs375781000; called by muse, mutect2, varscan2
- FAM71B | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 73/203 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs148633922, COSV100261721; called by muse, mutect2
- FAM71E2 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs922582517; called by muse, mutect2, varscan2
- FARP1 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); catalogued as rs754777712, COSV60344220; called by muse, mutect2, varscan2
- FASN | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 154/481 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as rs562846615; ClinVar: uncertain significance; called by muse, varscan2
- FBLN5 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 220/796 reads (28%) | SIFT tolerated (0.76); PolyPhen benign (0.05); catalogued as rs747580479; called by muse, varscan2
- FBXL19 | c.1720del p.V574Wfs*11 | Frame Shift Del (DEL) | VAF 88/274 reads (32%) | catalogued as COSV57942522; called by mutect2, pindel, varscan2
- FBXO41 | c.1913G>A p.R638Q | Missense Mutation (SNP) | VAF 145/471 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.24); catalogued as rs202061032, COSV54582430; called by muse, mutect2, varscan2
- FBXO7 | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 93/287 reads (32%) | catalogued as rs1370252127; called by muse, mutect2, varscan2
- FBXW10 | c.1861G>A p.V621M | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.886); catalogued as rs145231603; called by muse, mutect2, varscan2
- FBXW4 | c.1549C>T p.R517W | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140286143; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FCGBP | c.7336G>A p.V2446M | Missense Mutation (SNP) | VAF 79/661 reads (12%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.892); catalogued as rs1406238150, COSV99663637; called by muse, mutect2, varscan2
- FCHSD1 | c.622C>T p.R208C | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767896493, COSV71300783; called by muse, mutect2, varscan2
- FCHSD1 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 113/363 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs536442553, COSV53355163; called by muse, mutect2, varscan2
- FGF6 | c.38G>A p.R13Q | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs1565472687, COSV57403457; called by muse, mutect2, varscan2
- FGFR2 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 199/466 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.437); catalogued as CM940782; called by muse, mutect2, varscan2
- FGFRL1 | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.136); catalogued as rs372607043; called by muse, mutect2
- FILIP1L | c.1999C>T p.R667* (on ENST00000354552 / NM_182909.3; = p.R427* on NM_014890.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/134 reads (32%) | catalogued as COSV58764550; called by muse, mutect2, varscan2
- FKBP8 | c.682G>A p.G228S (on ENST00000222308 / NM_001308373.2; = p.G229S on NM_012181.5) | Missense Mutation (SNP) | VAF 84/229 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762107899, COSV99724356; called by muse, mutect2, varscan2
- FLG | c.7045G>A p.G2349R | Missense Mutation (SNP) | VAF 219/756 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.685); catalogued as rs1269991205, COSV100911606; called by muse, mutect2, varscan2
- FLNC | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 158/421 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV57962094; called by muse, mutect2, varscan2
- FLNC | c.3789C>T p.H1263= | Splice Region (SNP) | VAF 187/533 reads (35%) | catalogued as rs780906350; ClinVar: likely benign; called by muse, mutect2, varscan2
- FLNC | c.5431C>T p.R1811W | Missense Mutation (SNP) | VAF 158/440 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.849); catalogued as rs374794518; called by muse, mutect2, varscan2
- FLRT1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 106/296 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs941880462, COSV55367463; called by muse, mutect2, varscan2
- FMNL3 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 128/386 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as rs758167120; called by muse, mutect2, varscan2
- FMNL3 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.385); catalogued as rs747296458, COSV99526266; called by muse, mutect2, varscan2
- FNDC1 | c.2392G>A p.G798R | Missense Mutation (SNP) | VAF 107/307 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs757273488, COSV99794990; called by muse, mutect2, varscan2
- FOXA3 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 131/384 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1444890389, COSV56215273; called by muse, mutect2, varscan2
- FOXC2 | c.186C>G p.H62Q | Missense Mutation (SNP) | VAF 229/693 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.326); catalogued as rs761890099, COSV57444461; called by muse, mutect2, varscan2
- FRMD6 | c.46C>T p.R16C | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs138138697; called by muse, mutect2, varscan2
- FRMPD2 | c.824C>T p.A275V | Missense Mutation (SNP) | VAF 88/296 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs111596155, COSV59716312; called by muse, varscan2
- FRMPD2 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 70/197 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs145688226; called by muse, varscan2
- FRRS1 | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs201530272, COSV54926081; called by muse, mutect2, varscan2
- FUS | c.1397del p.X466_splice | Splice Site (DEL) | VAF 36/114 reads (32%) | catalogued as rs35711706; called by mutect2, pindel, varscan2
- FUT4 | c.741del p.D248Tfs*48 | Frame Shift Del (DEL) | VAF 93/312 reads (30%) | catalogued as rs746338726; called by mutect2, pindel, varscan2
- FZD7 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 128/316 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.849); catalogued as rs1334110194, COSV99636949; called by muse, mutect2, varscan2
- FZR1 | c.1334G>A p.R445H | Missense Mutation (SNP) | VAF 83/228 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475281091, COSV58051098; called by muse, mutect2, varscan2
- GABBR2 | c.2755G>A p.V919I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.077); catalogued as rs199985270, COSV52322735; ClinVar: uncertain significance; called by muse, mutect2
- GABRR2 | c.947C>T p.P316L | Missense Mutation (SNP) | VAF 87/234 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs756791995, COSV68766022, COSV68766401; called by muse, mutect2, varscan2
- GALNT13 | c.893A>T p.D298V | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV101223934; called by muse, mutect2, varscan2
- GALNT14 | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764961383, COSV61105686; called by muse, mutect2, varscan2
- GIGYF2 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 63/210 reads (30%) | catalogued as COSV65248163; called by muse, varscan2
- GIGYF2 | c.2416C>T p.R806* | Nonsense Mutation (SNP) | VAF 97/286 reads (34%) | catalogued as COSV65249671; called by muse, mutect2, varscan2
- GJB5 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 149/445 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs373605298; called by muse, mutect2, varscan2
- GLE1 | c.1385G>A p.R462H | Missense Mutation (SNP) | VAF 106/348 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs200012444, COSV104401620; called by muse, mutect2, varscan2
- GLT8D1 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 106/389 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.086); catalogued as rs758986162; called by muse, mutect2, varscan2
- GMIP | c.1844C>T p.S615L | Missense Mutation (SNP) | VAF 80/286 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1448417124, COSV52557330; called by muse, mutect2, varscan2
- GOLGA1 | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs184457003; called by muse, mutect2, varscan2
- GPATCH8 | c.2238_2240del p.R749del | In Frame Del (DEL) | VAF 26/102 reads (25%) | catalogued as rs778513845; called by pindel, varscan2
- GPATCH8 | c.1374_1377del p.S459Kfs*11 | Frame Shift Del (DEL) | VAF 23/62 reads (37%) | catalogued as rs748631863; called by mutect2, pindel, varscan2
- GPR161 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs571151360, COSV54790745; called by muse, mutect2, varscan2
- GPR32 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 93/268 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs893372939, COSV99567180; called by muse, mutect2, varscan2
- GPS1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs1407346478, COSV100135878; called by muse, mutect2, varscan2
- GRAMD2B | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 61/178 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs756364725, COSV53506767; called by muse, mutect2, varscan2
- GREB1 | c.2833G>A p.G945S | Missense Mutation (SNP) | VAF 194/531 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370772266; called by muse, varscan2
- GRIK3 | c.1530+1G>A p.X510_splice | Splice Site (SNP) | VAF 76/201 reads (38%) | catalogued as rs150709090, COSV100902481; called by muse, mutect2, varscan2
- GRM5 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 118/374 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199573699, COSV59593751; called by muse, mutect2, varscan2
- GRM8 | c.1955G>A p.R652Q | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs182088200, COSV58797967, COSV58825269; called by muse, mutect2, varscan2
- GSDME | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 156/595 reads (26%) | SIFT tolerated (0.56); PolyPhen benign (0.027); catalogued as rs140321823; ClinVar: uncertain significance; called by muse, varscan2
- GSN | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1014829124; called by muse, mutect2, varscan2
- GSTM5 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 100/291 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV56658295; called by muse, mutect2, varscan2
- GTF2H1 | c.1496G>A p.R499Q | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.07); catalogued as rs1318881331, COSV56380401, COSV99786685; called by muse, mutect2, varscan2
- HARS2 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 236/670 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs749799529; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HDGFL1 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); catalogued as rs1402599814; called by muse, mutect2, varscan2
- HEPH | c.2260C>T p.R754W (on ENST00000343002; = p.R487W on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/238 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.302); catalogued as rs201153564, COSV57964391; called by muse, mutect2, varscan2
- HEPH | c.3355C>A p.L1119I (on ENST00000343002; = p.L852I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 196/573 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV57970523; called by muse, varscan2
- HERC6 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 53/121 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as rs781134393, COSV52033247, COSV52033693; called by muse, mutect2, varscan2
- HIF3A | c.1880G>A p.S627N (on ENST00000377670 / NM_152795.4; = p.S558N on NM_022462.4) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.012); catalogued as COSV99355912; called by muse, mutect2, varscan2
- HK3 | c.2554C>T p.R852W | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs755391790, COSV52844309; called by muse, mutect2, varscan2
- HMGN5 | c.534del p.G179Vfs*48 | Frame Shift Del (DEL) | VAF 41/150 reads (27%) | catalogued as rs1556033122; called by mutect2, pindel, varscan2
- HMGXB4 | c.1267G>A p.V423M | Missense Mutation (SNP) | VAF 83/265 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.938); catalogued as rs565071032; called by muse, mutect2, varscan2
- HMX3 | c.68del p.P23Hfs*100 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | catalogued as rs779589617; called by mutect2, varscan2
- HOMER3 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.398); catalogued as rs538333527; called by muse, mutect2, varscan2
- HOXA3 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1212072086, COSV57829097; called by muse, mutect2, varscan2
- HPRT1 | c.157G>T p.V53L | Missense Mutation (SNP) | VAF 76/252 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as CM920355; called by muse, mutect2, varscan2
- HS6ST3 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100940150; called by muse, mutect2, varscan2
- HSD17B3 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 116/370 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as rs1029381659; called by muse, mutect2, varscan2
- HSPA12A | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 78/264 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1554878676; called by muse, mutect2, varscan2
- HTR4 | c.691C>T p.R231W | Missense Mutation (SNP) | VAF 88/272 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs140360260; called by muse, mutect2, varscan2
- HTRA3 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 99/349 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs754462983; called by muse, mutect2, varscan2
- HUWE1 | c.8986C>T p.R2996W | Missense Mutation (SNP) | VAF 133/423 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53346582; called by muse, mutect2, varscan2
- HYDIN | c.6974C>T p.A2325V | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.042); catalogued as rs542961391, COSV59265921; called by muse, mutect2, varscan2
- IBTK | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 70/263 reads (27%) | catalogued as COSV60394365; called by muse, mutect2, varscan2
- IFNA5 | c.268C>A p.L90I | Missense Mutation (SNP) | VAF 141/388 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as rs763935604; called by muse, mutect2, varscan2
- IFT74 | c.1694C>T p.T565I | Missense Mutation (SNP) | VAF 42/124 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV101197118; called by muse, varscan2
- IGFALS | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 198/558 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764069429, COSV51905553; called by muse, mutect2, varscan2
- IGLON5 | c.10_11del p.P4Cfs*42 | Frame Shift Del (DEL) | VAF 21/59 reads (36%) | catalogued as rs777644550; called by pindel, varscan2
- IL13 | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376870298, COSV100449426; called by muse, mutect2, varscan2
- IL1R2 | c.580G>A p.V194I | Missense Mutation (SNP) | VAF 116/343 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201409941; called by muse, mutect2, varscan2
- IL1RL2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 71/238 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as rs748205889, COSV51814833; called by muse, mutect2, varscan2
- ILDR1 | c.776G>A p.R259Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as rs1322210462; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 39/119 reads (33%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INSC | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.982); catalogued as rs1268965855; called by muse, mutect2, varscan2
- INSYN2A | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 128/368 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs372417174, COSV99733663; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 26/60 reads (43%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- IQSEC1 | c.1183C>T p.R395C | Missense Mutation (SNP) | VAF 140/323 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs754606659, COSV56227882; called by muse, mutect2, varscan2
- IQSEC1 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 203/487 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as rs753528211, COSV56226206; called by muse, mutect2, varscan2
- IRS1 | c.664T>A p.F222I | Missense Mutation (SNP) | VAF 135/367 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59335771; called by muse, mutect2, varscan2
- ITGA1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs764123493, COSV50883352; called by muse, mutect2, varscan2
- ITGA5 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 57/182 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.421); catalogued as rs897973104, COSV53219701; called by muse, mutect2, varscan2
- ITGA7 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs776189266, COSV99145097; called by muse, mutect2, varscan2
- ITGB3 | c.1942C>T p.R648W | Missense Mutation (SNP) | VAF 219/612 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs139166528, CM123723, COSV71384160; called by muse, mutect2, varscan2
- ITGB4 | c.3641G>A p.R1214H | Missense Mutation (SNP) | VAF 181/514 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); catalogued as rs139518734; called by muse, mutect2, varscan2
- ITPR3 | c.7768G>A p.V2590M | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65268281; called by muse, mutect2, varscan2
- JAK2 | c.3223G>A p.V1075M | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs775568041; called by muse, mutect2, varscan2
- JAKMIP1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV51547025; called by muse, mutect2, varscan2
- JAKMIP3 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 70/252 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs764557390; called by muse, mutect2, varscan2
- JARID2 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV59189436; called by muse, mutect2, varscan2
- JPH1 | c.1574C>T p.A525V | Missense Mutation (SNP) | VAF 138/413 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs752290170, COSV60614918, COSV60615551; called by muse, mutect2, varscan2
- JPH2 | c.1589C>T p.A530V | Missense Mutation (SNP) | VAF 39/128 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.105); catalogued as rs754961884; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KANK4 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 119/357 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs142004576; called by muse, mutect2, varscan2
- KCNA10 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.028); catalogued as rs868838468, COSV63904631; called by muse, mutect2, varscan2
- KCNJ10 | c.305del p.P102Rfs*96 | Frame Shift Del (DEL) | VAF 36/104 reads (35%) | catalogued as rs765409185; called by mutect2, varscan2
- KCNK9 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 201/587 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57287617; called by muse, mutect2, varscan2
- KCTD11 | c.484C>T p.R162* (on ENST00000333751 / NM_001363642.1; = p.R123* on NM_001002914.2) | Nonsense Mutation (SNP) | VAF 158/461 reads (34%) | catalogued as rs1384121385; called by muse, mutect2, varscan2
- KDM2B | c.3016del p.R1006Gfs*37 | Frame Shift Del (DEL) | VAF 72/226 reads (32%) | catalogued as rs1555288650, COSV65639291; called by mutect2, pindel, varscan2
- KDM5B | c.2527C>T p.R843W | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1189771603, COSV52503507; called by muse, mutect2, varscan2
- KIAA0895 | c.401G>A p.C134Y (on ENST00000297063 / NM_001100425.2; = p.C83Y on NM_015314.3) | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs775965678; called by muse, mutect2, varscan2
- KIAA1522 | c.2135del p.P712Lfs*104 (on ENST00000373480 / NM_001198972.2; = p.P771Lfs*104 on NM_020888.3) | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as rs1211049149; called by mutect2, pindel, varscan2
- KIAA1958 | c.2027G>A p.R676H | Missense Mutation (SNP) | VAF 147/428 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.059); catalogued as rs368441076; called by muse, mutect2, varscan2
- KIF19 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 101/303 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs199585407; called by muse, mutect2, varscan2
- KIF1A | c.3982C>T p.R1328C (on ENST00000320389 / NM_001379639.1; = p.R1320C on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 115/321 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as rs1444137658, COSV100239976; called by muse, mutect2, varscan2
- KIF26B | c.5157del p.S1720Afs*16 | Frame Shift Del (DEL) | VAF 82/329 reads (25%) | catalogued as rs1385639497; called by mutect2, pindel, varscan2
- KIF5B | c.2323C>T p.R775* | Nonsense Mutation (SNP) | VAF 63/194 reads (32%) | catalogued as COSV56652547; called by muse, mutect2, varscan2
- KIN | c.505del p.T169Lfs*9 | Frame Shift Del (DEL) | VAF 84/270 reads (31%) | catalogued as rs769387138, COSV65430366; called by mutect2, pindel, varscan2
- KLHL21 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 95/299 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.263); catalogued as rs554094853; called by muse, mutect2, varscan2
- KLKB1 | c.741G>A p.W247* | Nonsense Mutation (SNP) | VAF 202/601 reads (34%) | catalogued as COSV52993944; called by muse, mutect2, varscan2
- KMT2C | c.6415C>T p.R2139* | Nonsense Mutation (SNP) | VAF 42/134 reads (31%) | catalogued as rs1396109953, COSV51288645; called by muse, mutect2, varscan2
- KMT2D | c.8641C>T p.R2881W | Missense Mutation (SNP) | VAF 160/488 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as rs763549369; called by muse, mutect2, varscan2
- KPNA5 | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as COSV62651057; called by muse, mutect2, varscan2
- KRTAP2-2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1319436088, COSV66952825; called by muse, mutect2, varscan2
- KRTAP4-12 | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 175/577 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs762855668, COSV67457992; called by muse, mutect2, varscan2
- LAMB4 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52716432; called by muse, mutect2, varscan2
- LAMC3 | c.3305G>A p.R1102H | Missense Mutation (SNP) | VAF 247/786 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1377008496; called by muse, mutect2, varscan2
- LANCL1 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 43/172 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.815); catalogued as COSV52064453; called by muse, mutect2, varscan2
- LARP1B | c.2216G>A p.R739H | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753196849; called by muse, mutect2, varscan2
- LARS2 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 145/435 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs200313557, COSV55526767; called by muse, mutect2, varscan2
- LCE1F | c.136G>A p.V46I | Missense Mutation (SNP) | VAF 149/462 reads (32%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.026); catalogued as rs553837591, COSV57668776; called by muse, mutect2, varscan2
- LCT | c.3931C>T p.R1311* | Nonsense Mutation (SNP) | VAF 101/298 reads (34%) | catalogued as rs1291540757, COSV51545152; called by muse, mutect2, varscan2
- LCT | c.1274C>T p.T425M | Missense Mutation (SNP) | VAF 195/506 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748907176, COSV51543639; called by muse, mutect2, varscan2
- LDLRAP1 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 88/240 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs554607440; called by muse, mutect2
- LENG9 | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.289); catalogued as rs1354928992; called by muse, mutect2, varscan2
- LEO1 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 74/249 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs774730401; called by muse, mutect2, varscan2
- LHX6 | c.407G>A p.R136Q (on ENST00000373755 / NM_001242334.2; = p.R165Q on NM_014368.5) | Missense Mutation (SNP) | VAF 111/283 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs866148672; called by muse, mutect2, varscan2
- LILRB4 | c.203C>A p.P68H | Missense Mutation (SNP) | VAF 36/596 reads (6%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.761); catalogued as COSV54407626; called by muse, mutect2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 108/326 reads (33%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMNTD2 | c.532C>T p.R178* | Nonsense Mutation (SNP) | VAF 24/58 reads (41%) | catalogued as rs759591329; called by muse, mutect2, varscan2
- LRP1 | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 9/190 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1335043783; called by muse, mutect2
- LRRC17 | c.1272del p.K424Nfs*12 | Frame Shift Del (DEL) | VAF 36/100 reads (36%) | catalogued as rs745668314; called by mutect2, varscan2
- LRRC20 | c.152A>G p.Q51R | Missense Mutation (SNP) | VAF 138/405 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1404732729; called by muse, mutect2, varscan2
- LRRC37A2 | c.2557C>T p.R853C | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.446); catalogued as rs1365423866; called by mutect2, varscan2
- LRRC4 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.053); catalogued as rs1448671642; called by muse, mutect2, varscan2
- LRRC59 | c.568C>T p.R190W | Missense Mutation (SNP) | VAF 97/298 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as rs1444626107; called by muse, mutect2, varscan2
- LRRIQ3 | c.1134del p.P379Lfs*26 | Frame Shift Del (DEL) | VAF 44/172 reads (26%) | catalogued as rs751977298; called by mutect2, pindel, varscan2
- LTBP3 | c.678del p.V227Wfs*2 | Frame Shift Del (DEL) | VAF 37/130 reads (28%) | catalogued as rs1349589786; called by mutect2, pindel, varscan2
- LYZL4 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 93/275 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.465); catalogued as rs367979069; called by muse, mutect2, varscan2
- LZTS3 | c.542del p.P181Rfs*26 | Frame Shift Del (DEL) | VAF 90/265 reads (34%) | catalogued as rs745647523; called by mutect2, pindel, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 12/54 reads (22%) | catalogued as rs752439249; called by mutect2, varscan2
- MADD | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.173); catalogued as rs376589140; called by muse, mutect2
- MAGEA3 | c.613G>A p.V205I | Missense Mutation (SNP) | VAF 156/479 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as rs1258965349; called by muse, mutect2, varscan2
- MAGEB4 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs370615666; called by muse, mutect2, varscan2
- MAGEE1 | c.32G>A p.R11H | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV100819499; called by muse, mutect2, varscan2
- MAML1 | c.2377G>A p.V793I | Missense Mutation (SNP) | VAF 136/394 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.058); catalogued as rs762585296, COSV99483632; called by muse, mutect2, varscan2
- MAP1A | c.2636G>A p.R879H | Missense Mutation (SNP) | VAF 139/424 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs192228146; called by muse, mutect2, varscan2
- MAP1S | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 256/700 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs1283523997; called by muse, mutect2, varscan2
- MAP1S | c.1508G>A p.R503H | Missense Mutation (SNP) | VAF 83/195 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.308); catalogued as rs953061039, COSV60721962; called by muse, mutect2, varscan2
- MAP3K11 | c.2037del p.T680Rfs*267 | Frame Shift Del (DEL) | VAF 27/114 reads (24%) | catalogued as rs1554987893, COSV58421031; called by mutect2, pindel, varscan2
- MAP3K6 | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 152/264 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62887232; called by muse, mutect2, varscan2
- MAP9 | c.1700del p.K567Rfs*13 | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as rs1215313075; called by mutect2, pindel, varscan2
- MAPK4 | c.253G>A p.G85S | Missense Mutation (SNP) | VAF 85/301 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); catalogued as rs1474431030; called by muse, mutect2, varscan2
- MAPK8IP3 | c.2524G>A p.V842M | Missense Mutation (SNP) | VAF 114/371 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.038); catalogued as rs764582997, COSV51715591; called by muse, mutect2, varscan2
- MAST3 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 111/319 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs942590760, COSV99446937; called by muse, mutect2, varscan2
- MBD3L2 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 206/1288 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.12); catalogued as rs1447743368; called by muse, mutect2, varscan2
- MCEE | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as rs779113206, COSV54905813, COSV54906834; called by muse, mutect2, varscan2
- MCM3 | c.901C>T p.R301* (on ENST00000229854 / NM_001366374.2; = p.R291* on NM_002388.6 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 37/108 reads (34%) | catalogued as rs748281978; called by muse, mutect2, varscan2
- MDN1 | c.13204G>A p.D4402N | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs367773841; called by muse, mutect2, varscan2
- MDN1 | c.3829C>T p.R1277* | Nonsense Mutation (SNP) | VAF 86/264 reads (33%) | catalogued as rs548739528, COSV65524282; called by muse, mutect2, varscan2
- MED12 | c.4637C>T p.T1546M | Missense Mutation (SNP) | VAF 70/190 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs1423751717, COSV61330728; called by muse, mutect2, varscan2
- MED19 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 104/314 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1311611160, COSV54708993; called by mutect2, varscan2
- MED26 | c.1222G>A p.G408R | Missense Mutation (SNP) | VAF 145/389 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs776081520; called by muse, mutect2, varscan2
- MEGF10 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 50/205 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1173217783, COSV57255579; called by muse, mutect2, varscan2
- MEGF6 | c.1847G>A p.R616Q | Missense Mutation (SNP) | VAF 14/393 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.165); catalogued as rs937294961, COSV53888215; called by muse, mutect2
- MEPCE | c.434dup p.G146Rfs*7 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | catalogued as rs760012501; called by mutect2, varscan2
- METTL2B | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 65/210 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52310551; called by muse, mutect2, varscan2
- MGAT5B | c.2056G>A p.A686T (on ENST00000569840 / NM_001199172.2; = p.A684T on NM_144677.3) | Missense Mutation (SNP) | VAF 111/301 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1405678969, COSV56924909, COSV56934271; called by muse, mutect2, varscan2
- MIGA1 | c.1188+10dup | Splice Region (INS) | VAF 24/70 reads (34%) | catalogued as rs764028419; called by mutect2, varscan2
- MLH3 | c.1755del p.E586Nfs*24 | Frame Shift Del (DEL) | VAF 66/157 reads (42%) | catalogued as rs751465048; called by mutect2, varscan2
- MMAA | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 71/224 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.344); catalogued as rs367609164; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP24 | c.1714_1716del p.K572del | In Frame Del (DEL) | VAF 164/477 reads (34%) | catalogued as rs757961147; called by mutect2, pindel, varscan2
- MOGAT3 | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 105/313 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs551948278, COSV56173245; called by muse, mutect2, varscan2
- MOGAT3 | c.230C>T p.S77L | Missense Mutation (SNP) | VAF 114/350 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.09); catalogued as rs775889618, COSV56173557; called by muse, mutect2, varscan2
- MON1A | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.526); catalogued as rs148539732; called by muse, mutect2, varscan2
- MORC1 | c.2234dup p.E746Gfs*15 | Frame Shift Ins (INS) | VAF 16/58 reads (28%) | catalogued as rs1389536933; called by mutect2, pindel*, varscan2
- MORN1 | c.1127del p.P376Rfs*57 | Frame Shift Del (DEL) | VAF 35/112 reads (31%) | catalogued as COSV66006490; called by mutect2, pindel, varscan2
- MPHOSPH10 | c.1328G>A p.R443H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs201469945; called by muse, mutect2, varscan2
- MPRIP | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 82/235 reads (35%) | catalogued as rs1457416122, COSV100505762; called by muse, mutect2, varscan2
- MRGPRX1 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as COSV100245975, COSV57106069; called by muse, mutect2, varscan2
- MROH2A | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.604); catalogued as rs908456415; called by muse, varscan2
- MSTO1 | c.1705G>A p.V569M | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1223757265; called by muse, mutect2, varscan2
- MTF2 | c.737C>T p.T246M | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs368305569; called by muse, mutect2, varscan2
- MUC12 | c.10082C>T p.T3361M (on ENST00000379442; = p.T3218M on NM_001164462.1) | Missense Mutation (SNP) | VAF 92/3328 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1292087714; called by muse, mutect2
- MUC19 | c.461del p.K154Sfs*87 | Frame Shift Del (DEL) | VAF 41/115 reads (36%) | catalogued as rs537060918; called by mutect2, varscan2
- MUC4 | c.9119C>T p.P3040L | Missense Mutation (SNP) | VAF 172/631 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.722); catalogued as rs781582657; called by muse, varscan2
- MVD | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs754060502; called by muse, mutect2
- MYBPC1 | c.979G>A p.G327S (on ENST00000550270 / NM_206820.2; = p.G352S on NM_002465.4) | Missense Mutation (SNP) | VAF 101/300 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs370213838; called by muse, mutect2, varscan2
- MYBPC3 | c.194C>T p.T65M | Missense Mutation (SNP) | VAF 103/289 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.963); catalogued as rs753300898, COSV57030718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYCBP2 | c.12992C>A p.A4331D (on ENST00000357337; = p.A4369D on NM_015057.5) | Missense Mutation (SNP) | VAF 88/289 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV62015669; called by mutect2, varscan2
- MYCBP2 | c.3829del p.Y1277Mfs*3 (on ENST00000357337; = p.Y1315Mfs*3 on NM_015057.5) | Frame Shift Del (DEL) | VAF 62/237 reads (26%) | catalogued as COSV62029492; called by mutect2, pindel, varscan2
- MYCBPAP | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 48/107 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201047283; called by muse, mutect2, varscan2
- MYH11 | c.3530C>T p.T1177M | Missense Mutation (SNP) | VAF 204/544 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs201391947; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH6 | c.4307G>A p.R1436H | Missense Mutation (SNP) | VAF 221/574 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs142556730; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH6 | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 170/516 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs767124357, COSV62454978; ClinVar: uncertain significance; called by muse, varscan2
- MYO18A | c.4888C>T p.R1630W | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757050642, COSV62873642; called by muse, mutect2, varscan2
- MYO18A | c.4114C>T p.R1372W | Missense Mutation (SNP) | VAF 82/215 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1046179825, COSV62867366; called by muse, mutect2, varscan2
- MYO18B | c.6806C>T p.T2269M | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.401); catalogued as rs201327023; called by muse, mutect2, varscan2
- MYO1D | c.1813C>T p.R605C | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs375202047; called by muse, mutect2, varscan2
- MYO3A | c.3938G>A p.R1313H | Missense Mutation (SNP) | VAF 82/277 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs142853143, COSV56319295; called by muse, mutect2, varscan2
- MYO5B | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 121/330 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs190998983, COSV53218427; called by muse, mutect2, varscan2
- MYO7A | c.4471G>A p.V1491M | Missense Mutation (SNP) | VAF 90/217 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs369768947; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO7B | c.3857G>A p.R1286Q | Missense Mutation (SNP) | VAF 134/414 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375117051; called by muse, mutect2, varscan2
- MYORG | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0.053); catalogued as rs1282552678, COSV99898625; called by muse, mutect2
- MYRF | c.2232del p.K745Rfs*45 (on ENST00000278836 / NM_001127392.3; = p.K736Rfs*45 on NM_013279.4) | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | catalogued as COSV99606396; called by mutect2, pindel, varscan2
- MZT2A | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 90/264 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs777626407, COSV58312238; called by muse, varscan2
- N4BP2 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 69/204 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs533904341, COSV54700185; called by muse, mutect2, varscan2
- N4BP3 | c.340C>T p.R114C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs771415478; called by muse, mutect2, varscan2
- NAA60 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.041); catalogued as rs371294887; called by muse, mutect2, varscan2
- NANOGNB | c.427C>T p.H143Y | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.95); PolyPhen benign (0.083); catalogued as rs1393420217; called by muse, mutect2
- NASP | c.478dup p.T160Nfs*10 | Frame Shift Ins (INS) | VAF 58/195 reads (30%) | catalogued as rs1212178296; called by mutect2, varscan2
- NBEAL2 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs377660462; called by muse, mutect2, varscan2
- NBPF12 | c.2381C>T p.A794V | Missense Mutation (SNP) | VAF 57/486 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.979); catalogued as COSV58775290; called by muse, mutect2, varscan2
- NCOR1 | c.3064G>A p.V1022I | Missense Mutation (SNP) | VAF 87/258 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs371483872, COSV52003729; called by muse, mutect2, varscan2
- NDFIP2 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54530297; called by muse, mutect2, varscan2
- NDNF | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 44/130 reads (34%) | catalogued as rs1425613951, COSV101113071; called by muse, varscan2
- NDST2 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 126/385 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.348); catalogued as rs574275291; called by muse, mutect2, varscan2
- NDUFA10 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 80/253 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.517); catalogued as rs755759707; called by muse, mutect2, varscan2
- NEB | c.4342G>A p.G1448R | Missense Mutation (SNP) | VAF 85/239 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200002537, COSV51429406; called by muse, mutect2, varscan2
- NEB | c.2294C>T p.T765M | Missense Mutation (SNP) | VAF 78/223 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs762693524; called by muse, mutect2, varscan2
- NEK3 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 108/357 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765927889; called by muse, mutect2, varscan2
- NELFA | c.560C>T p.A187V (on ENST00000542778; = p.A176V on NM_005663.5) | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as rs770531900, COSV61608224; called by muse, mutect2, varscan2
- NELL2 | c.2168G>A p.R723H | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs765900708; called by muse, mutect2, varscan2
- NEURL4 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); catalogued as rs756202643, COSV59756455; called by muse, mutect2, varscan2
- NFAT5 | c.4241C>T p.S1414L | Missense Mutation (SNP) | VAF 100/321 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs201563281; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NIBAN1 | c.1436G>A p.R479Q | Missense Mutation (SNP) | VAF 75/221 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371316368; called by muse, mutect2, varscan2
- NKX6-1 | c.1048A>G p.S350G | Missense Mutation (SNP) | VAF 96/260 reads (37%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs751750031, COSV99879977; called by muse, varscan2
- NLRC3 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 141/388 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.708); catalogued as rs750986719; called by muse, mutect2, varscan2
- NLRP2 | c.241C>T p.R81* | Nonsense Mutation (SNP) | VAF 140/364 reads (38%) | catalogued as rs755054890, COSV54752403; called by muse, mutect2, varscan2
- NLRP6 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.98); catalogued as rs147824160; called by muse, mutect2, varscan2
- NLRX1 | c.418G>A p.G140R | Missense Mutation (SNP) | VAF 97/261 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1475733289; called by muse, mutect2, varscan2
- NNT | c.2500G>A p.V834I | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs372546826, COSV52925736; called by muse, mutect2, varscan2
- NOD2 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 167/424 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.454); catalogued as rs148516118, CM030413, COSV56055090; ClinVar: likely benign; called by muse, mutect2, varscan2
- NPRL2 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 76/194 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51602369; called by muse, mutect2, varscan2
- NR0B1 | c.862C>T p.R288C | Missense Mutation (SNP) | VAF 224/621 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD128640, COSV100973523; called by muse, mutect2, varscan2
- NR4A2 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 62/150 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.284); catalogued as rs1431470780, COSV100277503, COSV59895514; called by muse, mutect2, varscan2
- NRBP2 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.954); catalogued as rs1554652946; called by muse, mutect2, varscan2
- NSUN2 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 92/273 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371887249; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NT5C1A | c.673G>A p.V225I | Missense Mutation (SNP) | VAF 112/280 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.244); catalogued as rs755869403; called by muse, mutect2, varscan2
- NTF4 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as rs776576559; called by muse, mutect2, varscan2
- NTNG1 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 18/61 reads (30%) | catalogued as COSV53978019; called by muse, mutect2, varscan2
- NTNG2 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 83/218 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); catalogued as rs1315897345, COSV100647437; called by muse, mutect2, varscan2
- NTRK1 | c.1231_1233del p.K411del | In Frame Del (DEL) | VAF 162/589 reads (28%) | catalogued as rs768558242; called by pindel, varscan2
- NTRK1 | c.1729G>A p.G577S | Missense Mutation (SNP) | VAF 174/509 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121964866, CM961050; called by muse, mutect2, varscan2
- NUAK2 | c.1324del p.L442Cfs*38 | Frame Shift Del (DEL) | VAF 65/223 reads (29%) | catalogued as rs753375361; called by mutect2, pindel, varscan2
- NUMBL | c.324G>A p.A108= | Splice Region (SNP) | VAF 81/221 reads (37%) | catalogued as COSV99424967; called by muse, varscan2
- NUP205 | c.3920G>A p.R1307Q | Missense Mutation (SNP) | VAF 41/127 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs774676240; called by muse, mutect2, varscan2
- NXF1 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 85/223 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs781026286, COSV53673080; called by muse, mutect2, varscan2
- NXPH3 | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 188/528 reads (36%) | SIFT tolerated (1); PolyPhen probably damaging (0.993); catalogued as rs146367019, COSV60872749; called by muse, mutect2, varscan2
- OGA | c.1783A>G p.N595D | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as COSV63381907; called by muse, mutect2, varscan2
- OPHN1 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs1422309868; called by muse, mutect2, varscan2
- OPRM1 | c.582G>A p.W194* | Nonsense Mutation (SNP) | VAF 85/212 reads (40%) | catalogued as COSV57681749, COSV57687784; called by muse, mutect2, varscan2
- OR2B6 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs750115578, COSV55128674; called by muse, mutect2, varscan2
- OR2L13 | c.597del p.F199Lfs*2 | Frame Shift Del (DEL) | VAF 109/348 reads (31%) | catalogued as rs1157797094; called by mutect2, pindel, varscan2
- OR2T34 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.588); catalogued as rs779030084, COSV60901135, COSV60902204; called by muse, mutect2, varscan2
- OR6C2 | c.333del p.L112Sfs*23 | Frame Shift Del (DEL) | VAF 51/224 reads (23%) | catalogued as rs753142851, COSV59515782; called by mutect2, pindel, varscan2
- OR6J1 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 50/147 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs998555137, COSV73329726; called by muse, mutect2, varscan2
- OSM | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.397); catalogued as rs141628229; called by muse, mutect2, varscan2
- OSMR | c.1849del p.T617Qfs*20 | Frame Shift Del (DEL) | VAF 85/304 reads (28%) | catalogued as rs762315064; called by mutect2, pindel, varscan2
- OTUD6A | c.116C>T p.T39M | Missense Mutation (SNP) | VAF 132/391 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs765873831, COSV57973837; called by muse, mutect2, varscan2
- OXA1L | c.1322G>A p.R441H (on ENST00000285848; = p.R381H on NM_005015.5) | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.329); catalogued as rs114764871, COSV53538769; called by muse, mutect2, varscan2
- P2RY2 | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 61/164 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as rs1477088266; called by muse, mutect2, varscan2
- PACS1 | c.2527G>A p.A843T | Missense Mutation (SNP) | VAF 133/374 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as rs369846760; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PACSIN3 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 176/478 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as rs528940960; called by muse, mutect2, varscan2
- PANK4 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 106/268 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as rs745873482, COSV65866867; called by muse, mutect2, varscan2
- PAQR7 | c.242C>T p.A81V | Missense Mutation (SNP) | VAF 69/230 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs752395755, COSV65351610; called by muse, mutect2, varscan2
- PARD3B | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 83/289 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as rs755830374, COSV62504366; called by muse, mutect2, varscan2
- PAX1 | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 123/318 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.588); catalogued as COSV68271021; called by muse, mutect2, varscan2
- PCDH15 | c.1933G>A p.G645R | Missense Mutation (SNP) | VAF 80/296 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.178); catalogued as rs1444959563; called by muse, mutect2, varscan2
- PCDH7 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 100/308 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as rs1298790860; called by muse, mutect2, varscan2
- PCDH9 | c.1929del p.F643Lfs*19 | Frame Shift Del (DEL) | VAF 61/198 reads (31%) | catalogued as COSV60592893; called by mutect2, pindel, varscan2
- PCDHA8 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); catalogued as COSV65334627; called by muse, mutect2, varscan2
- PCDHB16 | c.1873C>T p.R625C | Missense Mutation (SNP) | VAF 371/1010 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); catalogued as COSV53362684; called by muse, mutect2, varscan2
- PCDHB4 | c.1472C>T p.P491L | Missense Mutation (SNP) | VAF 266/978 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.127); catalogued as rs782259034, COSV52023078; called by muse, varscan2
- PDE1B | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1258824137; called by muse, mutect2, varscan2
- PDLIM3 | c.422C>T p.A141V (on ENST00000284770 / NM_001257963.1; = p.A308V on NM_014476.6) | Missense Mutation (SNP) | VAF 192/584 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.015); catalogued as rs774383499, COSV52977921, COSV52979964; called by muse, varscan2
- PDPR | c.1105A>G p.M369V | Missense Mutation (SNP) | VAF 82/486 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs541394087, COSV99848095; called by muse, mutect2, varscan2
- PDSS1 | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 200/590 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.218); catalogued as rs147864501, COSV100873646; called by muse, mutect2, varscan2
- PEAK1 | c.2875_2878del p.V959Ffs*89 | Frame Shift Del (DEL) | VAF 93/355 reads (26%) | catalogued as rs1365640807; called by mutect2, pindel, varscan2
- PER1 | c.3533G>A p.R1178Q | Missense Mutation (SNP) | VAF 149/466 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs199584851; called by muse, mutect2, varscan2
- PER2 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 107/319 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs199703220, COSV54524653; called by muse, mutect2, varscan2
- PEX1 | c.1285G>A p.V429I | Missense Mutation (SNP) | VAF 62/225 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.083); catalogued as rs780349018, COSV50398917; called by muse, mutect2, varscan2
- PFKP | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754525827, COSV66896441; called by muse, mutect2, varscan2
- PHF3 | c.3408del p.V1137* | Frame Shift Del (DEL) | VAF 45/129 reads (35%) | catalogued as rs1163689977; called by mutect2, pindel, varscan2
- PHF8 | c.370G>A p.V124I (on ENST00000357988 / NM_001184896.1; = p.V88I on NM_015107.3) | Missense Mutation (SNP) | VAF 167/449 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199664796; called by muse, mutect2, varscan2
- PHRF1 | c.3242C>T p.P1081L (on ENST00000264555 / NM_001286581.2; = p.P1080L on NM_020901.4) | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as rs1179517256; called by muse, mutect2, varscan2
- PIAS4 | c.722G>A p.R241H | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); catalogued as rs977215281, COSV99518660; called by muse, mutect2, varscan2
- PIAS4 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 79/192 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs1017950383; called by muse, mutect2, varscan2
- PIGB | c.840del p.F280Lfs*12 | Frame Shift Del (DEL) | VAF 50/190 reads (26%) | catalogued as rs756552559; called by mutect2, varscan2
- PIGN | c.2577-5del | Splice Region (DEL) | VAF 34/135 reads (25%) | catalogued as rs138671843; ClinVar: benign / likely benign; called by mutect2, varscan2
- PIH1D1 | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 96/283 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.986); catalogued as rs199907330; called by muse, mutect2, varscan2
- PIK3C2G | c.1727del p.F576Sfs*15 | Frame Shift Del (DEL) | VAF 24/118 reads (20%) | catalogued as rs775364821; called by mutect2, varscan2
- PIK3R5 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 109/309 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as rs767127767, COSV52660555; called by muse, mutect2, varscan2
- PIMREG | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 133/343 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs369882202; called by muse, mutect2, varscan2
- PITPNM2 | c.3655G>A p.A1219T | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs1212043775, COSV54905021; called by muse, mutect2, varscan2
- PKD1 | c.2593A>G p.S865G | Missense Mutation (SNP) | VAF 138/383 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs1267840617; called by muse, mutect2, varscan2
- PKN3 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 77/231 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as rs770542091; called by muse, mutect2, varscan2
- PLA2G6 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as rs375131619; called by muse, varscan2
- PLAA | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs772440843; called by muse, mutect2, varscan2
- PLAAT1 | c.764T>C p.V255A (on ENST00000650797; = p.V150A on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/173 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.023); catalogued as COSV53232789; called by muse, mutect2, varscan2
- PLCE1 | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 157/434 reads (36%) | catalogued as rs1564806961, CM147219, COSV53341836; called by muse, mutect2, varscan2
- PLEC | c.9604G>A p.G3202R (on ENST00000322810 / NM_201380.4; = p.G3092R on NM_000445.5) | Missense Mutation (SNP) | VAF 250/691 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs782159227; called by muse, mutect2, varscan2
- PLEKHG4 | c.2989C>T p.R997C | Missense Mutation (SNP) | VAF 163/489 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763033199; called by muse, mutect2, varscan2
- PLK1 | c.1294G>A p.V432M | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.922); catalogued as rs762224700; called by muse, mutect2, varscan2
- PLXNA1 | c.4150C>T p.R1384C | Missense Mutation (SNP) | VAF 132/410 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs368240880; called by muse, mutect2, varscan2
- PLXNA3 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs181269464, COSV63754458; called by muse, mutect2, varscan2
- PLXNB2 | c.3736C>T p.R1246W | Missense Mutation (SNP) | VAF 108/314 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100833930; called by muse, mutect2, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 32/95 reads (34%) | catalogued as rs782076287; called by mutect2, varscan2
- PLXND1 | c.3078-3del | Splice Region (DEL) | VAF 35/134 reads (26%) | catalogued as rs1278682279; called by mutect2, pindel, varscan2
- PNKD | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs377569724; called by muse, mutect2, varscan2
- PNPLA6 | c.3332G>A p.R1111H (on ENST00000414982 / NM_001166111.2; = p.R1063H on NM_006702.5) | Missense Mutation (SNP) | VAF 318/883 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs777615874, COSV55376790; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PNPLA7 | c.2512C>T p.R838W | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs886362169, COSV53006370; called by muse, mutect2, varscan2
- POMT1 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 199/506 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs772590277, COSV61228264; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POMT1 | c.1550C>T p.A517V | Missense Mutation (SNP) | VAF 258/677 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs761439623; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPA1 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 104/300 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs749785473, COSV64684174; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs201240380; called by muse, mutect2, varscan2
- PPP2R3A | c.1599G>T p.K533N | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV99388186; called by muse, mutect2
- PPP4R1 | c.2000C>T p.T667M (on ENST00000400556 / NM_001042388.3; = p.T650M on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1184932139, COSV53281269; called by muse, mutect2, varscan2
- PPP6R1 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 103/255 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as rs748130721; called by muse, mutect2, varscan2
- PRICKLE2 | c.2242C>T p.R748C (on ENST00000295902; = p.R692C on NM_198859.4) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1559505999; called by muse, mutect2, varscan2
- PROKR2 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 254/672 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs776908572, COSV54087946; called by muse, mutect2, varscan2
- PRR12 | c.483del p.G162Afs*47 (on ENST00000615927; = p.G983Afs*47 on NM_020719.3) | Frame Shift Del (DEL) | VAF 130/348 reads (37%) | catalogued as rs758401922; called by mutect2, varscan2
- PRR23B | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as COSV61493538; called by muse, mutect2, varscan2
- PRR5 | c.317A>G p.Y106C (on ENST00000336985 / NM_181333.4; = p.Y97C on NM_015366.4) | Missense Mutation (SNP) | VAF 108/296 reads (36%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); catalogued as rs1056779456; called by muse, mutect2, varscan2
- PRSS55 | c.418G>A p.A140T | Missense Mutation (SNP) | VAF 112/357 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs545644807; called by muse, mutect2, varscan2
- PSG2 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 16/554 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100283743; called by muse, mutect2
- PSMB7 | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 98/318 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs758993178, COSV52329844; called by muse, mutect2, varscan2
- PSME3 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1229944094; called by muse, mutect2, varscan2
- PTBP1 | c.979G>A p.A327T (on ENST00000349038 / NM_031991.4; = p.A353T on NM_002819.5) | Missense Mutation (SNP) | VAF 48/168 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs766586041; called by muse, mutect2, varscan2
- PTGDR | c.1005del p.H336Tfs*34 | Frame Shift Del (DEL) | VAF 110/374 reads (29%) | catalogued as rs1367087640; called by mutect2, pindel, varscan2
- PTPRB | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs549500865, COSV57699066; called by muse, mutect2, varscan2
- PTPRG | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 88/263 reads (33%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as rs370618193; called by muse, mutect2, varscan2
- PWWP2A | c.1837G>A p.A613T | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1423676750; called by muse, mutect2, varscan2
- PYGB | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 86/304 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs202079661; called by muse, mutect2, varscan2
- R3HCC1 | c.941C>T p.S314L (on ENST00000411463; = p.S274L on NM_001136108.3) | Missense Mutation (SNP) | VAF 49/119 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs767889782, COSV56120157; called by muse, mutect2, varscan2
- R3HDML | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 153/481 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs138012908; called by muse, mutect2, varscan2
- RAB8B | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 80/226 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as COSV58489543; called by muse, mutect2, varscan2
- RABGEF1 | c.775C>T p.R259C (on ENST00000439720 / NM_001287061.2; = p.R246C on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs748826677; called by muse, mutect2, varscan2
- RAD9B | c.960del p.A321Qfs*26 | Frame Shift Del (DEL) | VAF 114/333 reads (34%) | catalogued as rs778121031; called by mutect2, pindel, varscan2
- RAI1 | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 133/381 reads (35%) | catalogued as COSV99883064; called by muse, mutect2, varscan2
- RAI1 | c.4397G>A p.R1466Q | Missense Mutation (SNP) | VAF 135/347 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs369962661; called by muse, mutect2, varscan2
- RALGAPA1 | c.2090dup p.H698Afs*9 | Frame Shift Ins (INS) | VAF 29/69 reads (42%) | catalogued as rs1344384185; called by mutect2, varscan2
- RALGAPA2 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 124/321 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs868064942; called by muse, mutect2, varscan2
- RAMP3 | c.344del p.P115Qfs*8 | Frame Shift Del (DEL) | VAF 150/600 reads (25%) | catalogued as rs763340102; called by pindel, varscan2
- RAPGEF4 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 52/139 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV51417315; called by muse, mutect2, varscan2
- RAPH1 | c.2929C>T p.R977C | Missense Mutation (SNP) | VAF 117/310 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs1413290737, COSV99864762; called by muse, mutect2, varscan2
- RASGRP1 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 116/322 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100172199; called by muse, mutect2, varscan2
- RASL11A | c.280del p.Q94Rfs*72 | Frame Shift Del (DEL) | VAF 28/143 reads (20%) | catalogued as COSV54080257; called by mutect2, pindel, varscan2
- RBFOX1 | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150941982; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBM15 | c.2501G>A p.R834H | Missense Mutation (SNP) | VAF 117/303 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100873450; called by muse, mutect2, varscan2
- RBPJ | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as rs141690523, COSV60753858; called by muse, mutect2, varscan2
- RBPJ | c.252del p.E85Nfs*21 | Frame Shift Del (DEL) | VAF 75/175 reads (43%) | catalogued as rs761285857; called by mutect2, varscan2
- RCAN2 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 69/246 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs556179069, COSV57815822; called by muse, mutect2, varscan2
- REPIN1 | c.1116del p.S373Pfs*242 | Frame Shift Del (DEL) | VAF 24/84 reads (29%) | catalogued as rs759247453; called by mutect2, varscan2
- RGL3 | c.1403G>A p.R468H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs751008312, COSV66508037; called by muse, varscan2
- RGPD4 | c.4642del p.R1548Efs*31 | Frame Shift Del (DEL) | VAF 105/678 reads (15%) | catalogued as rs773903730; called by mutect2, pindel, varscan2
- RGS16 | c.532C>T p.R178W | Missense Mutation (SNP) | VAF 231/708 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs149776657; called by muse, mutect2, varscan2
- RHBDF1 | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 98/250 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs754018001, COSV51956637; called by muse, mutect2, varscan2
- RHBDF1 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1316734030, COSV99244715; called by muse, mutect2, varscan2
- RHBG | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.381); catalogued as rs776794312, COSV54803928; called by muse, mutect2, varscan2
- RIIAD1 | c.161G>T p.R54I | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100419860; called by muse, mutect2
- RIMS4 | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV65720399; called by muse, mutect2, varscan2
- RNF146 | c.502C>T p.R168* (on ENST00000368314 / NM_001242850.2; = p.R167* on NM_030963.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 53/126 reads (42%) | catalogued as COSV58931327; called by muse, mutect2, varscan2
- RNF213 | c.14123G>A p.R4708H | Missense Mutation (SNP) | VAF 198/522 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as rs773098626, COSV60389684; called by muse, mutect2, varscan2
- RNF25 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 87/223 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as rs1302519500, COSV55309645; called by muse, mutect2, varscan2
- RNF26 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 107/354 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs758538200; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 109/302 reads (36%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- RPS2 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.46); catalogued as rs1192932025; called by muse, mutect2, varscan2
- RSRC1 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.073); catalogued as rs560342468; called by muse, mutect2, varscan2
- RUFY4 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 109/307 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs749470049; called by muse, mutect2, varscan2
- RUSF1 | c.679G>A p.V227M | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766266663, COSV59129961; called by muse, mutect2, varscan2
- RYR1 | c.2270G>A p.R757H | Missense Mutation (SNP) | VAF 86/262 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs929824581, COSV62094113, COSV62101088; called by muse, mutect2
- RYR1 | c.11707C>T p.R3903W | Missense Mutation (SNP) | VAF 131/401 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1376763642, COSV62096661; called by muse, mutect2, varscan2
- SAC3D1 | c.1001G>A p.R334Q | Missense Mutation (SNP) | VAF 115/324 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs770834599, COSV57245672; called by muse, mutect2, varscan2
- SAMD3 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 32/81 reads (40%) | catalogued as rs991510398, COSV60775280; called by muse, mutect2, varscan2
- SAPCD2 | c.802C>T p.R268C | Missense Mutation (SNP) | VAF 93/202 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as rs551321017, COSV68836607; called by muse, mutect2, varscan2
- SATB2 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 107/318 reads (34%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs142825652, COSV99612002; ClinVar: benign; called by muse, mutect2, varscan2
- SBNO2 | c.1585C>T p.R529C | Missense Mutation (SNP) | VAF 69/240 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1382240119; called by muse, mutect2, varscan2
- SBNO2 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 66/177 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376023611; called by muse, mutect2, varscan2
- SBSN | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 101/522 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.147); catalogued as rs1255566431; called by muse, varscan2
- SCAF1 | c.3872del p.P1291Hfs*54 | Frame Shift Del (DEL) | VAF 73/253 reads (29%) | catalogued as COSV100566949; called by mutect2, pindel, varscan2
- SCART1 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 147/648 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.724); catalogued as rs906476958; called by muse, mutect2, varscan2
- SCCPDH | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs201201896; called by muse, mutect2, varscan2
- SCN11A | c.3466C>T p.R1156C | Missense Mutation (SNP) | VAF 66/181 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs571721216, COSV56565730; called by muse, mutect2, varscan2
- SCN4B | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 105/330 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1265062815, COSV61251899; called by muse, mutect2, varscan2
- SCN5A | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT tolerated (1); PolyPhen probably damaging (0.936); catalogued as rs779687673, CM1211223, COSV61128315; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCNN1B | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 183/423 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs749944710; called by muse, mutect2, varscan2
- SCT | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 77/178 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1040466999; called by muse, mutect2, varscan2
- SCYL1 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 75/197 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.067); catalogued as rs762057890; called by muse, mutect2, varscan2
- SEC16A | c.4121C>T p.S1374L | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs763169052; called by muse, mutect2, varscan2
- SEL1L | c.1600G>T p.G534C | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60919537, COSV60920043; called by muse, mutect2, varscan2
- SEMA3B | c.1367C>T p.T456M | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1553706193, COSV57113391; called by muse, mutect2, varscan2
- SEPTIN5 | c.319G>A p.V107M | Missense Mutation (SNP) | VAF 103/299 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63530312; called by muse, mutect2, varscan2
- SETD7 | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 95/268 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV56799503; called by muse, mutect2, varscan2
- SETD9 | c.451G>A p.V151I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs750339308; called by muse, mutect2, varscan2
- SETDB1 | c.2849del p.P950Qfs*16 | Frame Shift Del (DEL) | VAF 62/167 reads (37%) | catalogued as rs1220025296; called by mutect2, varscan2
- SEZ6L | c.809C>T p.T270M | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371478865; called by muse, mutect2, varscan2
- SGSM3 | c.493C>T p.R165C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139798144; called by muse, mutect2, varscan2
- SGSM3 | c.1040C>T p.A347V | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs145959285; called by muse, mutect2, varscan2
- SH2D1A | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 79/248 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.299); catalogued as COSV63578628; called by muse, mutect2, varscan2
- SH3BP4 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.171); catalogued as rs373888787; called by muse, mutect2, varscan2
- SHROOM4 | c.627G>T p.E209D | Missense Mutation (SNP) | VAF 158/501 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV56787777; called by muse, mutect2, varscan2
- SIN3B | c.2357G>A p.R786H | Missense Mutation (SNP) | VAF 163/441 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1213483828; called by muse, mutect2, varscan2
- SIPA1L3 | c.5122G>A p.E1708K | Missense Mutation (SNP) | VAF 86/220 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.058); catalogued as rs748028255, COSV55924737; called by muse, mutect2, varscan2
- SIRPA | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 147/398 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as rs755396026, COSV61540980; called by muse, mutect2, varscan2
- SKIDA1 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs1043336865; called by muse, mutect2, varscan2
- SLC12A4 | c.2708G>A p.R903H | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as rs750495285; called by muse, mutect2, varscan2
- SLC16A7 | c.1255G>A p.V419M | Missense Mutation (SNP) | VAF 68/214 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs201787046; called by muse, mutect2, varscan2
- SLC17A7 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99075802; called by muse, mutect2, varscan2
- SLC19A1 | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 68/151 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs759889380; called by muse, mutect2, varscan2
- SLC19A2 | c.1006G>A p.V336M | Missense Mutation (SNP) | VAF 167/463 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148047353; called by muse, mutect2, varscan2
- SLC22A13 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 80/234 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs377117410; called by muse, mutect2, varscan2
- SLC2A11 | c.901C>T p.R301W (on ENST00000345044 / NM_001024938.4; = p.R308W on NM_030807.5) | Missense Mutation (SNP) | VAF 130/372 reads (35%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.849); catalogued as rs200581467; called by muse, mutect2, varscan2
- SLC30A3 | c.1042G>A p.V348I | Missense Mutation (SNP) | VAF 137/454 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.05); catalogued as rs200925410; called by muse, mutect2, varscan2
- SLC30A3 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs567778975, COSV51985477, COSV99274025; called by muse, mutect2, varscan2
- SLC32A1 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as rs940895631; called by muse, mutect2, varscan2
- SLC35F6 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 59/204 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs762934984; called by muse, mutect2, varscan2
- SLC38A10 | c.2974dup p.D992Gfs*84 | Frame Shift Ins (INS) | VAF 28/103 reads (27%) | catalogued as rs762295813; called by mutect2, varscan2
- SLC39A4 | c.1697C>T p.A566V (on ENST00000301305 / NM_001374839.1; = p.A541V on NM_017767.3) | Missense Mutation (SNP) | VAF 134/320 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as rs1048832107; called by muse, mutect2, varscan2
- SLC43A2 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 173/475 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs750497073; called by muse, mutect2, varscan2
- SLC4A5 | c.3267del p.A1091Pfs*17 | Frame Shift Del (DEL) | VAF 33/119 reads (28%) | catalogued as rs1558864722; called by mutect2, pindel, varscan2
- SLC5A3 | c.78dup p.A27Cfs*6 | Frame Shift Ins (INS) | VAF 46/84 reads (55%) | catalogued as rs1569416317; called by mutect2, varscan2
- SLC6A11 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 115/350 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1193789777; called by muse, mutect2, varscan2
- SLC6A18 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 223/618 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs779752482, COSV99722191; called by muse, varscan2
- SLC6A18 | c.1829G>A p.R610H | Missense Mutation (SNP) | VAF 273/714 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1000807243, COSV99722093; called by muse, varscan2
- SLC6A2 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 221/610 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs557196282, COSV54921528; called by muse, mutect2, varscan2
- SLCO1B3 | c.833dup p.P280Afs*6 | Frame Shift Ins (INS) | VAF 82/259 reads (32%) | catalogued as rs751405974; called by mutect2, varscan2
- SLFN11 | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.015); catalogued as rs541053267, COSV100390291; called by muse, mutect2, varscan2
- SLFN5 | c.2093del p.P698Lfs*21 | Frame Shift Del (DEL) | VAF 45/161 reads (28%) | catalogued as rs745817019; called by mutect2, pindel, varscan2
- SLITRK1 | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 74/190 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as rs1202208817; called by muse, mutect2, varscan2
- SLPI | c.306dup p.N103Qfs*4 | Frame Shift Ins (INS) | VAF 60/156 reads (38%) | catalogued as rs745834619; called by mutect2, varscan2
- SMAD3 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 205/625 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV59280523, COSV59280801; called by muse, mutect2, varscan2
- SMOC1 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 176/519 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.143); catalogued as rs750347811; called by muse, varscan2
- SMTN | c.1336G>A p.V446M | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs540090792, COSV100295071, COSV60778742; called by muse, mutect2, varscan2
- SMTN | c.1605del p.S536Vfs*33 | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | catalogued as rs758895137; called by mutect2, varscan2
- SNIP1 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.048); catalogued as rs754170290; called by muse, mutect2, varscan2
- SNX25 | c.1913del p.N638Ifs*51 | Frame Shift Del (DEL) | VAF 80/216 reads (37%) | catalogued as rs768873484; called by mutect2, varscan2
- SOGA1 | c.326C>A p.P109Q | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.908); catalogued as rs1199560415; called by muse, mutect2
- SOST | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 132/367 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs541123476, COSV100059580; called by muse, mutect2, varscan2
- SOX8 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 86/227 reads (38%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.715); catalogued as rs567390186; called by muse, mutect2, varscan2
- SPAG9 | c.1861C>T p.R621C (on ENST00000262013 / NM_001130528.3; = p.R607C on NM_003971.6) | Missense Mutation (SNP) | VAF 105/307 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs993441677, COSV56233468; called by muse, mutect2, varscan2
- SPATA5 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 93/205 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs539850739, COSV56774121; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPG11 | c.6176G>A p.R2059Q | Missense Mutation (SNP) | VAF 159/447 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs757619567; called by muse, mutect2, varscan2
- SPN | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.104); catalogued as rs754074948; called by muse, mutect2, varscan2
- SPRYD4 | c.572G>A p.W191* | Nonsense Mutation (SNP) | VAF 72/188 reads (38%) | catalogued as COSV100358418; called by muse, mutect2, varscan2
- SPSB4 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1277516500; called by muse, mutect2, varscan2
- SREBF1 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.166); catalogued as rs780437419, COSV99889303; called by muse, mutect2, varscan2
- SRGN | c.115C>T p.R39C | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs557632542, COSV54344667; called by muse, mutect2, varscan2
- SRMS | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 89/305 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.009); catalogued as rs1434697730; called by muse, mutect2, varscan2
- SSC4D | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.321); catalogued as rs144685336; called by muse, mutect2, varscan2
- SSTR4 | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs374915518; called by muse, mutect2, varscan2
- ST6GALNAC4 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 104/282 reads (37%) | PolyPhen probably damaging (0.999); catalogued as rs755023922; called by muse, mutect2, varscan2
- ST8SIA2 | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 161/504 reads (32%) | PolyPhen possibly damaging (0.49); catalogued as rs1425349825, COSV51567220; called by muse, mutect2, varscan2
- STK36 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 89/294 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs750683279; called by muse, mutect2, varscan2
- STOML2 | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 90/260 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761625496, COSV100493708; called by muse, mutect2, varscan2
- STRA6 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 208/622 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs529201894; called by muse, mutect2, varscan2
- STUM | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 81/273 reads (30%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as rs139902713; called by muse, mutect2, varscan2
- SUV39H2 | c.996+1G>A p.X332_splice (on ENST00000354919 / NM_001193424.2; = p.X272_splice on NM_024670.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 38/115 reads (33%) | catalogued as COSV57953728; called by muse, mutect2
- SVOPL | c.976dup p.D326Gfs*18 (on ENST00000419765; = p.D174Gfs*18 on NM_174959.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 110/378 reads (29%) | catalogued as rs769304357; called by mutect2, varscan2
- SYCP1 | c.173del p.N58Mfs*34 | Frame Shift Del (DEL) | VAF 21/93 reads (23%) | catalogued as rs1482391429; called by mutect2, pindel, varscan2
- SYCP1 | c.2376del p.D793Tfs*65 | Frame Shift Del (DEL) | VAF 22/68 reads (32%) | catalogued as rs745637836; called by mutect2, varscan2
1,306 further variants in this file (586 protein-altering or splice-affecting, 455 silent, 265 other) are not listed here.
